Somatic mutation profile of tumor specimen ALCH-B1J9-TTP1-A (aliquot ALCH-B1J9-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1J9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.6 years (27,613 days).
Specimen ALCH-B1J9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aeab967-010d-40f9-b791-88c3af593979.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1J9-NB1-A (Blood Derived Normal), aliquot ALCH-B1J9-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/865e805a-c03c-4a89-aaaf-5bb6d2e4c6f9

The open-access MAF lists 592 somatic variants for this specimen: 400 protein-altering or splice-affecting, 132 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 132, Nonsense Mutation 35, Intron 29, RNA 13, Splice Site 11, Splice Region 10, 3'UTR 5, 5'UTR 5, 3'Flank 4, 5'Flank 4, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA8 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864309703, CM162287, COSV53791343; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 49/434 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 27/288 reads (9%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCA6 | c.3888G>C p.K1296N | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV52641886; called by muse, mutect2
- ACTRT1 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100947790; called by muse, mutect2
- ALDH7A1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs745921838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF11 | c.2674A>G p.I892V | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs933337294; called by muse, mutect2, varscan2
- ATP2B2 | c.2262G>T p.R754S (on ENST00000352432; = p.R720S on NM_001683.5) | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV59511064; called by muse, mutect2
- AZIN2 | c.640G>C p.A214P | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53857257; called by muse, mutect2
- BAHCC1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs368421163; called by muse, mutect2, varscan2
- BCHE | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs747438953; ClinVar: uncertain significance; called by muse, mutect2
- BCL11A | c.1735G>A p.A579T (on ENST00000335712 / NM_001365609.1; = p.A613T on NM_018014.4) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.685); catalogued as COSV59633591; called by muse, mutect2
- BHLHE40 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV99848030; called by muse, mutect2
- BLID | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 47/463 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV73340205; called by muse, mutect2, varscan2
- C15orf40 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1456650872; called by muse, mutect2
- C2CD2L | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs1345476891, COSV100371153, COSV60884010; called by muse, mutect2
- CACNA1F | c.5131C>A p.P1711T | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100544722, COSV59905550; called by muse, mutect2
- CACNA1H | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.257); catalogued as rs766768686, COSV61988218; called by muse, mutect2
- CD14 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs778015907; called by muse, mutect2
- CD200R1 | c.334G>T p.D112Y (on ENST00000471858 / NM_170780.3; = p.D135Y on NM_138806.4) | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55599974, COSV99867749; called by muse, mutect2
- CD300E | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60790275; called by muse, mutect2, varscan2
- CDH9 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 39/587 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs867964392, COSV50259663; called by muse, mutect2
- CDK13 | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476141; called by muse, mutect2
- CDR1 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs868748648, COSV65164198; called by muse, mutect2
- CLASRP | c.462G>A p.K154= | Splice Region (SNP) | VAF 16/161 reads (10%) | catalogued as rs1317756884; called by muse, mutect2, varscan2
- CNTNAP3 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV52677950; called by muse, mutect2
- COG8 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs568491704; called by muse, mutect2
- CSMD1 | c.5251G>T p.G1751* (on ENST00000520002; = p.G1750* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 26/310 reads (8%) | catalogued as COSV59343147; called by muse, mutect2
- CSMD1 | c.2383C>A p.H795N (on ENST00000520002; = p.H794N on NM_033225.6) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100149902; called by muse, mutect2
- CUBN | c.3698C>G p.S1233C | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1022552396; called by muse, mutect2
- DAW1 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1318905024, COSV100006163; called by muse, mutect2
- DDC | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373529153; called by muse, mutect2, varscan2
- DDR2 | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 38/714 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs55973200; called by muse, mutect2
- DLG2 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 31/440 reads (7%) | catalogued as COSV54680698; called by muse, mutect2
- DNMT3A | c.1473G>A p.E491= | Splice Region (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99264714; called by muse, mutect2
- EPHA3 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV60702276; called by muse, mutect2
- F9 | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD1514985, CM940706; called by muse, mutect2, varscan2
- FAM47C | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as rs1338749507, COSV63726254; called by muse, mutect2
- FANCC | c.1533G>T p.L511= | Splice Region (SNP) | VAF 18/435 reads (4%) | catalogued as COSV100002801; called by muse, mutect2
- FAT4 | c.7156G>A p.V2386I | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV100628964; called by muse, mutect2
- FCRLA | c.76G>T p.A26S (on ENST00000367959; = p.A9S on NM_032738.4) | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV52686033; called by muse, mutect2, varscan2
- FLNA | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs782067087, COSV61039883; called by muse, mutect2, varscan2
- FSD2 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 18/322 reads (6%) | catalogued as COSV58010777; called by muse, mutect2
- GDPD3 | c.767+3G>A | Splice Region (SNP) | VAF 16/212 reads (8%) | catalogued as rs779749501; called by muse, mutect2
- GNB5 | c.229G>A p.D77N (on ENST00000261837 / NM_016194.4; = p.D35N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1445306908; called by muse, mutect2, varscan2
- GOLT1A | c.221dup p.V75Cfs*25 | Frame Shift Ins (INS) | VAF 41/321 reads (13%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- HHLA1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1455055931; called by muse, mutect2
- HR | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.023); catalogued as CM076234; called by muse, mutect2
- HRNR | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 52/792 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754161004; called by muse, mutect2
- INHBA | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54222835; called by muse, mutect2, varscan2
- JAK2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs369833874; called by muse, mutect2
- KCNF1 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 6/101 reads (6%) | catalogued as COSV54461978; called by muse, mutect2
- KCNQ3 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs377725346, COSV66464287; ClinVar: uncertain significance; called by muse, mutect2
- KLHL34 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1011142790; called by muse, mutect2, varscan2
- KLK3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV58099807; called by muse, mutect2
- KRT9 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99879335; called by muse, mutect2
- LINGO3 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as COSV101347281; called by muse, mutect2, varscan2
- LMOD3 | c.1427C>A p.P476Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV70456221; called by muse, mutect2, varscan2
- LONRF2 | c.1755G>T p.A585= | Splice Region (SNP) | VAF 34/337 reads (10%) | catalogued as COSV101111083; called by muse, mutect2
- LRP1B | c.6503G>A p.C2168Y | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67195334; called by muse, mutect2
- MACF1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 32/406 reads (8%) | catalogued as rs372116509; called by muse, mutect2
- MATK | c.344C>A p.P115H (on ENST00000310132 / NM_139355.3; = p.P116H on NM_002378.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100036183, COSV59555926; called by muse, mutect2
- MAX | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 57/603 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52418258; called by muse, mutect2
- MED21 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 66/429 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs758663759; called by muse, mutect2, varscan2
- MS4A5 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV99038292; called by muse, mutect2
- MYO15B | c.2532G>A p.Q844= | Splice Region (SNP) | VAF 17/141 reads (12%) | catalogued as COSV101647634; called by muse, mutect2
- MYO18B | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV59143205; called by muse, mutect2
- MYO18B | c.5116C>A p.Q1706K | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV59131001; called by muse, mutect2
- MYO3A | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 45/677 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.173); catalogued as COSV56327060; called by muse, mutect2
- MYO5A | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 54/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369831881; called by muse, mutect2
- NCAM1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs367901170; called by muse, mutect2, varscan2
- NKRF | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58661502; called by muse, mutect2, varscan2
- NMRK2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51455050; called by muse, mutect2
- NOL4 | c.1279G>T p.V427F | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52356313; called by muse, mutect2, varscan2
- OCA2 | c.1775C>A p.T592N | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); catalogued as CM981406; called by muse, mutect2
- OR2T3 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.088); catalogued as COSV62081781; called by muse, mutect2
- OR4S2 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV100412621, COSV56746067; called by muse, mutect2
- OR8G5 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100422566; called by muse, mutect2
- PCDH8 | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100131592; called by muse, mutect2, varscan2
- PCDHA2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 33/457 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV65369028; called by muse, mutect2
- PDHA2 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54781069; called by muse, mutect2
- PIP5K1A | c.1104G>T p.Q368H (on ENST00000368888 / NM_001135638.2; = p.Q355H on NM_003557.3) | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100576802; called by muse, mutect2, varscan2
- PKLR | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 30/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM971211; called by muse, mutect2
- PLXNA4 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV58155489, COSV58159449; called by muse, mutect2, varscan2
- POM121L12 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs370077416, COSV68692380; called by muse, mutect2, varscan2
- POTEE | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 48/635 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV100388449, COSV58239217; called by muse, mutect2
- PRUNE2 | c.4807G>T p.E1603* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | catalogued as COSV65045502; called by muse, mutect2
- PTGIS | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.409); catalogued as rs747759437; called by muse, mutect2
- PTPRD | c.4099G>T p.G1367C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100644732; called by muse, mutect2, varscan2
- RAX2 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs777949969; called by muse, mutect2, varscan2
- REG1B | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as rs984265564, COSV59306097; called by muse, mutect2
- RELN | c.3377G>T p.W1126L | Missense Mutation (SNP) | VAF 63/601 reads (10%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.953); catalogued as COSV59035494; called by muse, mutect2, varscan2
- RGPD8 | c.5272G>T p.E1758* | Nonsense Mutation (SNP) | VAF 24/462 reads (5%) | catalogued as rs773125163; called by muse, mutect2
- SCARA5 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV61571831; called by muse, mutect2
- SEC24B | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as rs1209418661; called by muse, mutect2
- SETD5 | c.2555C>G p.S852C | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs922404193, COSV56706960; called by muse, mutect2
- SIX4 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV99382286; called by muse, mutect2, varscan2
- SLC26A4 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM043870, CM981508; called by muse, mutect2, varscan2
- SLC5A12 | c.1244T>C p.M415T | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs1256399680; called by muse, mutect2
- SLITRK6 | c.1112C>A p.A371E | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV68391047; called by muse, mutect2, varscan2
- SMG5 | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs1371244649; called by muse, mutect2
- SORCS3 | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV63813405; called by muse, mutect2
- SOS1 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs199778219; called by muse, mutect2
- SUPT16H | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99359777; called by muse, mutect2
- SV2C | c.672C>A p.C224* | Nonsense Mutation (SNP) | VAF 44/528 reads (8%) | catalogued as COSV100455712; called by muse, mutect2
- TAF1L | c.3826C>G p.R1276G | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV54263482; called by muse, mutect2
- TENM2 | c.2440T>G p.C814G (on ENST00000518659 / NM_001122679.2; = p.C582G on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV69126654; called by muse, mutect2, varscan2
- TGFBR2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 36/566 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV55447471; called by muse, mutect2
- TLX3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99740846; called by muse, varscan2
- TMPRSS11D | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV52223210; called by muse, mutect2
- TNN | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV53421489; called by muse, mutect2
- TOGARAM1 | c.3239G>C p.G1080A | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100817882; called by muse, mutect2
- TRIM58 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs781284712; called by muse, varscan2
- TRPM3 | c.1359T>A p.N453K (on ENST00000357533 / NM_001366142.2; = p.N298K on NM_020952.6) | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV62596614; called by muse, mutect2
- TRPV1 | c.1245G>C p.L415F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99440250; called by muse, mutect2, varscan2
- TRPV6 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 26/221 reads (12%) | catalogued as COSV63891002; called by muse, mutect2, varscan2
- TTLL5 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54042139; called by muse, mutect2
- UNC80 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs994534779, COSV55883879; called by muse, mutect2
- VCAN | c.7712C>T p.T2571I | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV54106269; called by muse, mutect2
- VPS8 | c.2190-2A>T p.X730_splice (on ENST00000625842 / NM_001349294.1; = p.X728_splice on NM_015303.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/318 reads (9%) | catalogued as COSV54982338; called by muse, mutect2
- WDFY4 | c.435C>G p.Y145* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | catalogued as COSV57444129; called by muse, mutect2
- WSCD2 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs371743603, COSV99774753; called by muse, mutect2, varscan2
- ZFAT | c.2926G>T p.A976S | Missense Mutation (SNP) | VAF 44/530 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV64734656, COSV64735755; called by muse, mutect2
- ZNF385B | c.1242+1G>A p.X414_splice | Splice Site (SNP) | VAF 23/349 reads (7%) | catalogued as COSV100415925; called by muse, mutect2
- ABCC4 | c.3629+1G>T p.X1210_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- ABL2 | c.2704G>T p.A902S (on ENST00000502732 / NM_007314.4; = p.A887S on NM_005158.5) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AC024940.1 | n.4258-1G>C | Splice Site (SNP) | VAF 15/420 reads (4%) | called by muse, mutect2
- AC092143.1 | c.2060A>G p.Y687C | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM22 | c.2540G>C p.R847T | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); called by muse, mutect2
- ADAMTS9 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 24/347 reads (7%) | called by muse, mutect2
- ADAR | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2
- ADGRV1 | c.16538C>A p.A5513D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AGA | c.789G>T p.L263F | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- AGTPBP1 | c.1174C>T p.Q392* (on ENST00000357081 / NM_001330701.2; = p.Q352* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- AHNAK2 | c.8210C>A p.P2737H | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKIRIN1 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDOA | c.886C>T p.Q296* (on ENST00000642816 / NM_001243177.4; = p.Q242* on NM_184041.5) | Nonsense Mutation (SNP) | VAF 33/462 reads (7%) | called by muse, mutect2
- ALPK1 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANK1 | c.3319G>T p.A1107S | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2
- ANK2 | c.663A>T p.Q221H | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD34C | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ANKRD44 | c.2584A>G p.S862G | Missense Mutation (SNP) | VAF 29/407 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD50 | c.2680G>C p.D894H | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ANKS1B | c.2209A>T p.K737* | Nonsense Mutation (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- APBA2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ARFGEF2 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 74/851 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ARHGAP29 | c.2711A>G p.Q904R | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- ARL9 | c.745A>T p.T249S (on ENST00000640821 / NM_001363794.2; = p.T107S on NM_206919.2) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.018); called by muse, mutect2
- ASXL2 | c.31A>T p.R11W | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP1A3 | c.2715C>A p.Y905* (on ENST00000545399 / NM_001256214.2; = p.Y892* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- ATP2B2 | c.2261G>T p.R754M (on ENST00000352432; = p.R720M on NM_001683.5) | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- B3GALT1 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2
- BIRC6 | c.6265G>C p.E2089Q | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.618); called by muse, mutect2
- CACNA2D4 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CARMIL3 | c.1217+1G>C p.X406_splice | Splice Site (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2
- CCDC14 | c.1386G>T p.Q462H (on ENST00000488653; = p.Q414H on NM_022757.5) | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- CCDC39 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.112); called by muse, mutect2
- CCN3 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD101 | c.1918T>C p.C640R | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD207 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- CD34 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2
- CDC23 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CDC6 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 35/537 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- CDX2 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2
- CENPE | c.1808T>A p.L603Q | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- CEP295NL | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CEP63 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 52/728 reads (7%) | called by muse, mutect2
- CFAP46 | c.6696G>C p.Q2232H | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.08); called by muse, mutect2
- CFAP58 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- CHAF1A | c.2510G>A p.C837Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD4 | c.1510A>T p.T504S (on ENST00000357008 / NM_001363606.2; = p.T517S on NM_001273.5) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CHD8 | c.4888G>A p.D1630N (on ENST00000646647 / NM_001170629.2; = p.D1351N on NM_020920.4) | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRNA1 | c.431A>G p.D144G (on ENST00000261007 / NM_001039523.3; = p.D119G on NM_000079.4) | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- CILK1 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CLCN3 | c.2015A>T p.Q672L | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2
- CLU | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- CNDP1 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNTN5 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- COL19A1 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 40/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL9A3 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- CPE | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- CPN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 51/523 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CPS1 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 19/447 reads (4%) | called by muse, mutect2
- CTDP1 | c.632A>T p.H211L | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTSC | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 36/692 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- CUL5 | c.2024+1G>T p.X675_splice | Splice Site (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- CYBRD1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CYP7A1 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 31/555 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2
- DAW1 | c.1116G>T p.W372C | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DBR1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- DDHD1 | c.972T>A p.N324K (on ENST00000323669; = p.N521K on NM_030637.3) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX60 | c.4600G>T p.E1534* | Nonsense Mutation (SNP) | VAF 17/295 reads (6%) | called by muse, mutect2
- DDX60 | c.4027C>G p.P1343A | Missense Mutation (SNP) | VAF 18/363 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DIDO1 | c.1710G>C p.K570N | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DISC1 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- DLL3 | c.574C>G p.R192G | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.426); called by muse, mutect2
- DMD | c.2784A>C p.R928S | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- DMGDH | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- DNAH12 | c.897+1G>T p.X299_splice | Splice Site (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- DNM1L | c.1831C>G p.P611A (on ENST00000549701 / NM_012062.5; = p.P574A on NM_005690.4) | Missense Mutation (SNP) | VAF 27/519 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- DOCK4 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPP6 | c.1273G>T p.E425* (on ENST00000377770 / NM_001364500.2; = p.E363* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- DST | c.2149G>A p.E717K (on ENST00000361203 / NM_001374722.1; = p.E391K on NM_001723.6) | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- DYNC2H1 | c.10282G>A p.D3428N | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2
- E2F7 | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2
- EEPD1 | c.1177-2A>T p.X393_splice | Splice Site (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2
- EHBP1 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- ENTPD7 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVX2 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FAM209A | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- FBLN2 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FBLN7 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- FBXL19 | c.1706_1713del p.G569Afs*115 | Frame Shift Del (DEL) | VAF 12/144 reads (8%) | called by mutect2, pindel
- FBXL4 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- FSD1 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); called by muse, mutect2
- GAB1 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GATA3 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); called by muse, mutect2
- GEMIN5 | c.4157G>T p.R1386L | Missense Mutation (SNP) | VAF 25/372 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.07); called by muse, mutect2
- GEMIN6 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- GIGYF2 | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- GPALPP1 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- GPT2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- GRIK5 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2
- GRK4 | c.308T>A p.L103Q (on ENST00000398052 / NM_182982.3; = p.L71Q on NM_005307.3) | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.725); called by muse, mutect2
- GTPBP4 | c.836T>A p.F279Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HASPIN | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- HCN4 | c.2573A>G p.H858R | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- HGF | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 35/493 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HGSNAT | c.1543-2A>T p.X515_splice | Splice Site (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- HHIPL1 | c.1665G>T p.M555I | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2
- HMCN2 | c.13882G>A p.D4628N | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HRH2 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2
- HRH2 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HYOU1 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- IFT80 | c.824T>A p.I275N | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- IGFN1 | c.1628C>A p.S543Y (on ENST00000295591 / NM_001367841.1; = p.S3000Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- IGKV1-6 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 41/601 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- IGSF10 | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- IL12RB2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 52/729 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- IL23R | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- INSM2 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 31/448 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- INTS7 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- INTS9 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2
- ITGB5 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.748); called by muse, mutect2
- JMJD1C | c.5135G>T p.G1712V | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JPH1 | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2
- KANSL3 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- KCNAB1 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2
- KCNB1 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCND2 | c.1404C>A p.S468R | Missense Mutation (SNP) | VAF 70/772 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.034); called by muse, mutect2
- KIAA0895 | c.208G>T p.A70S (on ENST00000297063 / NM_001100425.2; = p.A19S on NM_015314.3) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2
- KRT71 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- KSR2 | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2
- LDLRAD3 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LGSN | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- LILRB2 | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRFN5 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1B | c.1707C>A p.Y569* | Nonsense Mutation (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- LRRC4C | c.1108G>C p.A370P | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); called by muse, mutect2
- LRRC72 | c.628A>C p.K210Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2
- MACROD2 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MAFA | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); called by muse, mutect2
- MAGEB6B | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- MAML1 | c.2402C>G p.S801C | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); called by muse, mutect2
- MANBA | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MAP10 | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- MAT2A | c.654G>T p.M218I | Missense Mutation (SNP) | VAF 35/615 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2
- MDGA2 | c.2038T>A p.C680S (on ENST00000399232 / NM_001113498.2; = p.C382S on NM_182830.4) | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MDGA2 | c.1654G>T p.E552* (on ENST00000399232 / NM_001113498.2; = p.E254* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 18/428 reads (4%) | called by muse, mutect2
- MEGF10 | c.2928C>A p.C976* | Nonsense Mutation (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2
- MEGF8 | c.3044G>T p.C1015F (on ENST00000251268 / NM_001271938.2; = p.C948F on NM_001410.3) | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MEOX1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2
- MGA | c.8398G>C p.E2800Q (on ENST00000219905 / NM_001164273.1; = p.E2591Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- MINDY2 | c.837G>T p.W279C | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- MOGS | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MPP4 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.773); called by muse, mutect2
- MRPL37 | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 28/377 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC19 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.97); called by muse, mutect2
- MYH11 | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NAALADL2 | c.2256C>A p.H752Q | Missense Mutation (SNP) | VAF 37/628 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- NDST2 | c.1421A>C p.H474P | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- NEK3 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- NELL1 | c.1677G>C p.E559D | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.352); called by muse, mutect2
- NPIPB2 | c.509G>T p.C170F (on ENST00000399147; = p.C30F on NM_001355514.1) | Missense Mutation (SNP) | VAF 36/643 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2
- NPL | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.018); called by muse, mutect2
- NRCAM | c.2033C>A p.T678K (on ENST00000379028 / NM_001371124.1; = p.T662K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.103); called by muse, mutect2
- NUP133 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 35/228 reads (15%) | called by muse, mutect2, varscan2
- OBSCN | c.16462C>G p.Q5488E | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OLFM4 | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OPRM1 | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); called by muse, mutect2
- OPRPN | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- OR10J1 | c.903C>A p.C301* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2
- OR10R2 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5H15 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PASK | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2
- PAX3 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2
- PCDHGB6 | c.2239A>T p.T747S | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDCL2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.172); called by muse, mutect2
- PEG3 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PGBD4 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGR | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); called by muse, mutect2
- PHAX | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- PHF20L1 | c.2812G>T p.D938Y | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- PLCG2 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PLG | c.1984A>T p.T662S | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PNRC1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2
- POP4 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- PPCDC | c.380G>C p.W127S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPCDC | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIA4 | c.-176C>T | Splice Region (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- PPP1R2B | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2
- PPP4C | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRDM12 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2
- PRKD2 | c.1034A>C p.E345A | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- PROKR1 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2
- PRPF40A | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- PRRG3 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- PRRG4 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- PTPRC | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRC | c.75G>T p.G25= | Splice Region (SNP) | VAF 21/281 reads (7%) | called by muse, mutect2
- PTPRH | c.1350G>T p.L450F | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.859); called by muse, mutect2
- RABGAP1L | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- RABGAP1L | c.2408A>C p.Q803P | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2
- RADIL | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAG2 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.478); called by muse, mutect2
- RBM23 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- RBP3 | c.3112C>T p.L1038F | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RC3H2 | c.2433C>A p.F811L | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- RGPD3 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- RIMS2 | c.2428G>T p.E810* (on ENST00000666250 / NM_001348490.2; = p.E618* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- RIMS2 | c.4244A>T p.Q1415L (on ENST00000666250 / NM_001348490.2; = p.Q986L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ROBO2 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 38/700 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2
- RP1L1 | c.5732C>A p.A1911E | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2
- RTEL1 | c.3644C>A p.S1215Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2
- RYR2 | c.2718G>T p.P906= | Splice Region (SNP) | VAF 35/318 reads (11%) | called by muse, mutect2, varscan2
- SAGE1 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SCEL | c.823A>G p.R275G (on ENST00000349847 / NM_144777.3; = p.R255G on NM_003843.4) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- SEC24C | c.634A>T p.S212C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SEMA6B | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SERPINA6 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- SH2D1A | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 85/477 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SH3GL3 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- SHROOM2 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- SIGLEC1 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- SIX4 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.341); called by muse, mutect2
- SLC22A10 | c.1293G>C p.Q431H | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC24A1 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- SLC33A1 | c.1318A>T p.S440C | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A8 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2
- SLC5A8 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- SMC1A | c.2061G>A p.E687= | Splice Region (SNP) | VAF 49/554 reads (9%) | called by muse, mutect2
- SMR3A | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- SND1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- SORL1 | c.3664A>G p.T1222A | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- SPATA18 | c.908T>A p.L303* | Nonsense Mutation (SNP) | VAF 29/428 reads (7%) | called by muse, mutect2
- SPOCK1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- STAU2 | c.13A>T p.K5* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- STK11IP | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- STX8 | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2
- SUSD5 | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- SYNE1 | c.22876G>A p.E7626K (on ENST00000367255 / NM_182961.4; = p.E7555K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYNE2 | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 40/725 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TAS1R2 | c.2490G>T p.M830I | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2
- TEP1 | c.4475C>A p.P1492H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TMEM117 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNFSF18 | c.517A>T p.I173L | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNN | c.1910C>A p.T637K | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- TNS3 | c.3928+1G>T p.X1310_splice | Splice Site (SNP) | VAF 30/347 reads (9%) | called by muse, mutect2
- TNS3 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAPPC9 | c.3446G>C p.*1149Sext*14 | Nonstop Mutation (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- TRPC5 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPM2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TRPV5 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TYROBP | c.341G>C p.*114Sext*17 | Nonstop Mutation (SNP) | VAF 31/571 reads (5%) | called by muse, mutect2
- UBA2 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- UBE4B | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2
- UGT3A1 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- UNC45B | c.1964G>T p.R655M | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- WASHC2C | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 14/313 reads (4%) | called by muse, mutect2
- WDFY4 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2
- WDR6 | c.3182C>T p.S1061L | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2
- WDR97 | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK4 | c.3351C>A p.S1117R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- YAP1 | c.859C>T p.P287S (on ENST00000282441 / NM_001130145.3; = p.P249S on NM_006106.5) | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- YLPM1 | c.4769G>T p.G1590V | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ZAN | c.5356C>G p.L1786V | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZCCHC24 | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2
- ZMPSTE24 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- ZNF227 | c.992A>T p.K331M | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF331 | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF469 | c.5041C>A p.Q1681K (on ENST00000437464; = p.Q1709K on NM_001367624.2) | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- ZNF566 | c.839A>T p.E280V | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF584 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF761 | c.1952G>C p.G651A | Missense Mutation (SNP) | VAF 24/560 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.115); called by muse, mutect2
- ZNF800 | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF829 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- ZNF831 | c.1153G>T p.V385F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF878 | c.1405C>G p.H469D | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- A2ML1 | c.3414C>A p.A1138= | Silent (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- ABCD3 | c.1347G>T p.T449= | Silent (SNP) | VAF 30/321 reads (9%) | catalogued as rs758559803; called by muse, mutect2
- AC011448.1 | c.471G>T p.L157= | Silent (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- ACAN | c.2589C>A p.A863= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- ACAN | c.7153C>A p.R2385= (on ENST00000560601 / NM_001369268.1; = p.R2309= on NM_001135.3) | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- ADAMTS12 | c.843G>A p.L281= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as rs138213093; called by muse, mutect2
- ANKRD26 | c.3219C>G p.L1073= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as rs556481944; called by muse, mutect2, varscan2
- APBA2 | c.909G>A p.K303= | Silent (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- AQP8 | c.73A>C p.R25= | Silent (SNP) | VAF 17/286 reads (6%) | called by muse, mutect2
- ARAP1 | c.3285C>T p.F1095= (on ENST00000393609 / NM_001040118.2; = p.F850= on NM_015242.4) | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs976345726; called by muse, mutect2
- ARHGAP23 | c.30G>A p.G10= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- ARHGEF12 | c.2151A>T p.P717= | Silent (SNP) | VAF 41/393 reads (10%) | called by muse, mutect2
- ARHGEF25 | c.1068G>A p.L356= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as COSV54089606; called by muse, mutect2
- ATP1A2 | c.1068G>A p.V356= | Silent (SNP) | VAF 20/378 reads (5%) | catalogued as rs1160242709, COSV100767634; called by muse, mutect2
- ATP1A2 | c.2541C>T p.I847= | Silent (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- ATP2A1 | c.2280C>T p.F760= | Silent (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2, varscan2
- BPIFB1 | c.1113C>A p.A371= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- BTD | c.1368A>G p.T456= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- CACNA1I | c.5637C>A p.A1879= | Silent (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- CACNA2D3 | c.1318C>A p.R440= | Silent (SNP) | VAF 22/377 reads (6%) | catalogued as COSV99871175; called by muse, mutect2
- CAPNS1 | c.690C>T p.I230= | Silent (SNP) | VAF 29/320 reads (9%) | catalogued as COSV53084195; called by muse, mutect2
- CCDC107 | c.783C>T p.P261= | Silent (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- CCNB3 | c.1098G>C p.S366= | Silent (SNP) | VAF 42/396 reads (11%) | catalogued as rs201480633; called by muse, mutect2, varscan2
- CCNL2 | c.1149G>T p.R383= | Silent (SNP) | VAF 17/193 reads (9%) | called by muse, mutect2
- CD80 | c.168T>A p.V56= | Silent (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- CEP89 | c.696T>C p.Y232= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs753975093; called by muse, mutect2
- CFAP61 | c.1047C>T p.D349= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CFAP61 | c.1578C>T p.I526= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- CLEC4G | c.75G>T p.V25= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2
- CNKSR3 | c.882C>T p.T294= | Silent (SNP) | VAF 23/352 reads (7%) | catalogued as rs748705440; called by muse, mutect2
- CPEB1 | c.1848G>T p.L616= (on ENST00000617958; = p.L551= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- CRB1 | c.540C>T p.G180= | Silent (SNP) | VAF 24/410 reads (6%) | called by muse, mutect2
- CSMD1 | c.7803G>T p.L2601= (on ENST00000520002; = p.L2600= on NM_033225.6) | Silent (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
- DALRD3 | c.1563G>C p.L521= (on ENST00000341949 / NM_001009996.3; = p.L354= on NM_018114.5) | Silent (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- DDR2 | c.1626C>A p.A542= | Silent (SNP) | VAF 38/708 reads (5%) | catalogued as COSV100906287; called by muse, mutect2
- DDX60L | c.427C>T p.L143= | Silent (SNP) | VAF 17/240 reads (7%) | catalogued as rs746804270; called by muse, mutect2
- DNAH10 | c.6036G>T p.L2012= (on ENST00000409039; = p.L1951= on NM_207437.3) | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- DYSF | c.1311G>T p.T437= | Silent (SNP) | VAF 30/391 reads (8%) | catalogued as rs150093305; called by muse, mutect2
- ETNPPL | c.198G>T p.V66= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- FCRL2 | c.435C>T p.F145= | Silent (SNP) | VAF 23/531 reads (4%) | called by muse, mutect2
- FMN2 | c.1347C>T p.P449= | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- GDF10 | c.723G>A p.A241= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs368864625; called by muse, mutect2
- GFI1B | c.369C>G p.P123= | Silent (SNP) | VAF 15/367 reads (4%) | called by muse, mutect2
- GTPBP4 | c.837C>T p.F279= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1180805948, COSV62550811; called by muse, mutect2
- HCRTR2 | c.504G>T p.R168= | Silent (SNP) | VAF 39/602 reads (6%) | called by muse, mutect2
- HELZ2 | c.5130C>T p.F1710= (on ENST00000467148 / NM_001037335.2; = p.F1141= on NM_033405.3) | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as COSV71295710; called by muse, varscan2
- HIPK2 | c.2862G>A p.G954= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- HOXA9 | c.411G>T p.L137= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV58655779; called by muse, mutect2, varscan2
- HTR2C | c.816C>A p.A272= | Silent (SNP) | VAF 28/455 reads (6%) | catalogued as COSV99349445, COSV99349788; called by muse, mutect2
- IFNAR2 | c.288A>T p.T96= | Silent (SNP) | VAF 12/426 reads (3%) | called by muse, mutect2
- IGHV3-49 | c.297C>T p.I99= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as rs113334719; called by muse, mutect2, varscan2
- IGSF1 | c.1692C>T p.F564= | Silent (SNP) | VAF 24/374 reads (6%) | catalogued as COSV100812268; called by muse, mutect2
- IRS2 | c.3753C>T p.L1251= | Silent (SNP) | VAF 22/318 reads (7%) | catalogued as COSV65479542; called by muse, mutect2
- ITK | c.1485C>T p.V495= | Silent (SNP) | VAF 44/616 reads (7%) | called by muse, mutect2
- KCNS1 | c.783C>T p.R261= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- KIAA1614 | c.1836G>A p.L612= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as rs1202690164; called by muse, mutect2
- KRTAP19-2 | c.135A>G p.R45= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- LBP | c.720C>A p.A240= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- MARCHF1 | c.693C>A p.A231= (on ENST00000274056; = p.A214= on NM_017923.4) | Silent (SNP) | VAF 31/524 reads (6%) | called by muse, mutect2
- MCM7 | c.1494C>T p.R498= | Silent (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- MEGF8 | c.423G>T p.L141= | Silent (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- MMP27 | c.96G>A p.L32= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2
- MPDZ | c.489G>T p.L163= | Silent (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- MROH2A | c.3382C>T p.L1128= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs1001263551; called by muse, mutect2
- MROH7 | c.2910C>A p.L970= | Silent (SNP) | VAF 21/239 reads (9%) | catalogued as COSV59870809; called by muse, mutect2
- MTMR8 | c.1986G>A p.E662= | Silent (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- MYD88 | c.723C>T p.L241= | Silent (SNP) | VAF 43/596 reads (7%) | catalogued as rs151334142; ClinVar: likely benign; called by muse, mutect2
- NCCRP1 | c.27G>T p.A9= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- NDUFA4L2 | c.81C>T p.I27= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV61073333; called by muse, mutect2
- OR10D3 | c.858G>A p.L286= | Silent (SNP) | VAF 42/327 reads (13%) | called by muse, mutect2, varscan2
- OR14I1 | c.597C>A p.A199= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- OR14K1 | c.72G>T p.L24= | Silent (SNP) | VAF 22/300 reads (7%) | called by muse, mutect2
- OR2C3 | c.744G>T p.V248= | Silent (SNP) | VAF 64/405 reads (16%) | called by muse, mutect2, varscan2
- OR2T27 | c.570G>T p.T190= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV61281026; called by muse, mutect2, varscan2
- OR6C70 | c.714C>A p.T238= | Silent (SNP) | VAF 21/352 reads (6%) | called by muse, mutect2
- OR8I2 | c.657C>A p.I219= | Silent (SNP) | VAF 17/193 reads (9%) | called by muse, mutect2
- OSMR | c.1707C>T p.L569= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as rs756379833; called by muse, mutect2, varscan2
- PCDHA4 | c.324G>A p.V108= | Silent (SNP) | VAF 33/452 reads (7%) | called by muse, mutect2
- PCDHA6 | c.2061G>T p.A687= | Silent (SNP) | VAF 11/218 reads (5%) | catalogued as COSV65342936; called by muse, mutect2
- PCDHB15 | c.1899C>T p.R633= | Silent (SNP) | VAF 34/505 reads (7%) | catalogued as rs1469905804; called by muse, mutect2
- PIN1 | c.282G>A p.Q94= | Silent (SNP) | VAF 23/317 reads (7%) | called by muse, mutect2
- PKHD1 | c.3372G>A p.E1124= | Silent (SNP) | VAF 44/547 reads (8%) | catalogued as rs569065606, COSV100582886; called by muse, mutect2
- PPRC1 | c.3903G>C p.R1301= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- PRAMEF1 | c.903T>A p.T301= | Silent (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- PRKDC | c.7977G>T p.L2659= | Silent (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- PRRC2B | c.6268C>T p.L2090= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs369533990; called by muse, mutect2, varscan2
- PSAP | c.699G>T p.L233= | Silent (SNP) | VAF 32/520 reads (6%) | called by muse, mutect2
- PTGDR | c.204G>A p.L68= | Silent (SNP) | VAF 15/292 reads (5%) | catalogued as COSV100035479; called by muse, mutect2
- PTPN7 | c.504C>A p.T168= (on ENST00000495688; = p.T207= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs767353421; called by muse, mutect2, varscan2
- RAB3IL1 | c.381A>G p.R127= | Silent (SNP) | VAF 24/352 reads (7%) | called by muse, mutect2
- RAPGEF1 | c.1011C>A p.G337= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- RASAL2 | c.657C>T p.F219= | Silent (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- RLF | c.4980A>G p.V1660= | Silent (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- RNASE3 | c.45G>A p.L15= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV58960000; called by muse, mutect2
- RP1 | c.636G>C p.V212= | Silent (SNP) | VAF 25/491 reads (5%) | called by muse, mutect2
- RXFP3 | c.678G>T p.A226= | Silent (SNP) | VAF 30/241 reads (12%) | catalogued as COSV100347192; called by muse, mutect2, varscan2
- RYR2 | c.9774A>G p.P3258= | Silent (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- RYR3 | c.4260C>A p.G1420= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- SAMD7 | c.496C>T p.L166= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- SDCCAG8 | c.1020G>A p.V340= | Silent (SNP) | VAF 22/465 reads (5%) | catalogued as COSV59413521; called by muse, mutect2
- SDK1 | c.5295G>T p.L1765= | Silent (SNP) | VAF 29/336 reads (9%) | called by muse, mutect2
- SETDB1 | c.729G>T p.S243= | Silent (SNP) | VAF 17/424 reads (4%) | catalogued as COSV54981178, COSV54985251; called by muse, mutect2
- SFMBT2 | c.2619T>C p.P873= | Silent (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- SHANK1 | c.5586C>A p.A1862= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- SLC6A15 | c.51T>A p.T17= | Silent (SNP) | VAF 20/263 reads (8%) | called by muse, mutect2
- SLIT2 | c.1884A>G p.G628= | Silent (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- SMC3 | c.3528G>A p.R1176= | Silent (SNP) | VAF 20/298 reads (7%) | catalogued as rs779739612; called by muse, mutect2
- SND1 | c.537C>T p.T179= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as rs1316037467; called by muse, mutect2
- SORCS2 | c.3135G>A p.L1045= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- SP110 | c.930G>A p.K310= | Silent (SNP) | VAF 28/546 reads (5%) | catalogued as COSV99283739; called by muse, mutect2
- SPHKAP | c.1137T>A p.P379= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- SPOCK3 | c.603C>T p.C201= | Silent (SNP) | VAF 18/303 reads (6%) | catalogued as COSV62720761; called by muse, mutect2
- STX16 | c.504C>T p.A168= (on ENST00000371141 / NM_001001433.3; = p.A147= on NM_003763.6) | Silent (SNP) | VAF 13/238 reads (5%) | called by muse, mutect2
- SYN1 | c.723A>C p.T241= | Silent (SNP) | VAF 46/524 reads (9%) | called by muse, mutect2
- SYT13 | c.966C>T p.L322= | Silent (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- TADA1 | c.153C>T p.L51= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs748786511; called by muse, mutect2
- TASOR2 | c.5103T>C p.A1701= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as rs746656002; called by muse, mutect2
- TCF4 | c.472A>C p.R158= | Silent (SNP) | VAF 17/254 reads (7%) | catalogued as COSV100610671; called by muse, mutect2
- TEP1 | c.675C>T p.L225= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs773932679; called by muse, mutect2
- TLX3 | c.630C>G p.V210= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- TMC6 | c.615C>G p.L205= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- TMEM121B | c.1002C>A p.G334= | Silent (SNP) | VAF 14/275 reads (5%) | catalogued as rs1432917193; called by muse, mutect2
- TMEM41B | c.576T>C p.R192= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- TTC30A | c.1638G>A p.V546= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV63102242; called by muse, mutect2
- UBA2 | c.1866A>T p.A622= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- VEGFC | c.1014A>T p.T338= | Silent (SNP) | VAF 28/499 reads (6%) | called by muse, mutect2
- VPS13C | c.4528C>T p.L1510= (on ENST00000644861 / NM_020821.3; = p.L1467= on NM_017684.5) | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99829482; called by muse, mutect2
- WFS1 | c.291C>G p.A97= | Silent (SNP) | VAF 26/370 reads (7%) | called by muse, mutect2
- ZNF106 | c.4884C>G p.L1628= | Silent (SNP) | VAF 19/348 reads (5%) | catalogued as rs1384808153, COSV55515728; called by muse, mutect2
- ZNF281 | c.345G>A p.R115= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs763660466; called by muse, mutect2, varscan2
- ZNF729 | c.2973C>A p.P991= | Silent (SNP) | VAF 20/355 reads (6%) | catalogued as COSV62607683; called by muse, mutect2
- ZNF85 | c.111C>T p.Y37= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs1453415667; called by muse, mutect2
- AC092718.9 | chr16:81154330 G>T | 3'Flank (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- AC093802.1 | n.102G>A | RNA (SNP) | VAF 20/258 reads (8%) | catalogued as rs528268527; called by muse, mutect2
- AC097518.1 | n.94C>A | RNA (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- ADORA1 | c.342-14527G>C | Intron (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- ANKRD42 | c.138+59G>C | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700779 C>A | 3'Flank (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- C9orf62 | n.386C>G | RNA (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- CACNG4 | c.*624C>A | 3'UTR (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- CASP1 | c.-15G>A | 5'UTR (SNP) | VAF 24/397 reads (6%) | called by muse, mutect2
- CCDC110 | c.2461+875C>T | Intron (SNP) | VAF 26/400 reads (7%) | called by muse, mutect2
- CECR2 | c.*10G>A | 3'UTR (SNP) | VAF 11/279 reads (4%) | called by muse, mutect2
- CLK2P1 | n.594T>A | RNA (SNP) | VAF 26/468 reads (6%) | called by muse, mutect2
- COL6A4P1 | n.1059C>A | RNA (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- CRCP | c.46-554C>T | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as rs1157125471; called by muse, mutect2
- CSRNP1 | c.-106C>T | 5'UTR (SNP) | VAF 9/57 reads (16%) | catalogued as rs1029757611; called by muse, mutect2, varscan2
- DCHS2 | n.8013G>T | RNA (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- DCUN1D4 | c.414+492C>T | Intron (SNP) | VAF 20/257 reads (8%) | catalogued as rs1053745790; called by muse, mutect2
- DIRC1 | n.527C>A | RNA (SNP) | VAF 20/220 reads (9%) | catalogued as COSV100353133; called by muse, mutect2
- DNM2 | c.1493+14G>A | Intron (SNP) | VAF 19/346 reads (5%) | called by muse, mutect2
- FAM172BP | n.973A>T | RNA (SNP) | VAF 19/354 reads (5%) | called by muse, mutect2
- FAM90A27P | n.1130G>T | RNA (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- FBXL15 | c.-882C>G | 5'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, varscan2
- FTH1 | chr11:61968460 G>A | 5'Flank (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- GABRA3 | c.551+4673C>A | Intron (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- GAMT | c.328-46G>A | Intron (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- GNB3 | c.58-23C>A | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- GON4L | c.1788+94G>T | Intron (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- HCFC1R1 | c.152+55C>G | Intron (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- HDAC9 | c.2577+17T>C | Intron (SNP) | VAF 32/286 reads (11%) | called by muse, mutect2, varscan2
- HDGFL3 | c.607-5270G>T | Intron (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- ILKAP | c.1038+94G>T | Intron (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- KLHL7 | c.121-5861G>T | Intron (SNP) | VAF 34/514 reads (7%) | catalogued as COSV59164854; called by muse, mutect2
- KLHL7 | c.121-5860G>T | Intron (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- KLK7 | chr19:50983873 C>T | 5'Flank (SNP) | VAF 17/183 reads (9%) | catalogued as COSV58345018; called by muse, mutect2
- L1CAM | c.-109+682del | Intron (DEL) | VAF 31/208 reads (15%) | called by mutect2, pindel, varscan2
- LILRB4 | chr19:54662983 G>A | 5'Flank (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- LINC01235 | n.443G>T | RNA (SNP) | VAF 34/687 reads (5%) | called by muse, mutect2
- MAP4K1 | c.1531+28C>T | Intron (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- MDGA2 | c.281-41433C>A | Intron (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- MPRIP | c.2164-4378A>T | Intron (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2
- MSI2 | c.312+23746C>T | Intron (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- NAF1 | chr4:163127004 T>A | 3'Flank (SNP) | VAF 16/180 reads (9%) | catalogued as rs957122588; called by muse, mutect2
- NPL | c.230+129G>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs1367126612; called by muse, mutect2, varscan2
- NT5C1B-RDH14 | c.*97C>T | 3'UTR (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- OR9Q1 | c.-15+53545G>T | Intron (SNP) | VAF 30/332 reads (9%) | catalogued as rs1419158063; called by muse, mutect2
- PACRGL | c.-16-2611A>T | Intron (SNP) | VAF 12/339 reads (4%) | called by muse, mutect2
- PRMT6 | c.*6G>T | 3'UTR (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- SDC2 | c.-64G>T | 5'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SLC41A3 | c.274-5431T>C | Intron (SNP) | VAF 18/244 reads (7%) | catalogued as rs766261208; called by muse, mutect2
- SLC4A1 | c.*1295G>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- SNORD115-5 | n.39G>T | RNA (SNP) | VAF 30/430 reads (7%) | called by muse, mutect2
- SPNS1 | c.663+22G>T | Intron (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210163665 T>A | 3'Flank (SNP) | VAF 15/214 reads (7%) | called by muse, mutect2
- TK1 | chr17:78187085 G>T | 5'Flank (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- TMEM230 | c.-59G>A | 5'UTR (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- TUBB7P | n.1091C>T | RNA (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- UBE2D4 | c.24+1463A>G | Intron (SNP) | VAF 25/278 reads (9%) | called by muse, mutect2
- VPS33A | c.102+621G>A | Intron (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- XIST | n.10497G>A | RNA (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- ZNF497 | c.-111-272C>T | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
